Surgical pathology report (de-identified scan), TCGA case TCGA-FS-A1ZQ, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Essen, specimen TCGA-FS-A1ZQ-06A (Metastatic).

Prof.Dr
Direktor der

ICD-0-3

Melanoma, NOS 8720/3

Site: lung, NOS C34.9

for 7/24/11

Patient: XXXX
geb. *** **

Datum:

Translation of pathology report F

Sample

Gross Pathology

Cryofixed specimen with a weight of

Microscopic pathology

The H&E stained slide at hand shows an epitheloid malignant tumor with sparse amount of connective tissue. The tumor constitute approx. 90 percent of the tissue. The tumor cells show round to oval nuclei with granular chromatine.

There is a high nucleo/cytoplasmatic ratio. The mitotic count is 10 mitoses per square millimetre. The tumor cells have a middle sized pigmented cytoplasm.

The tumor shows a sheet like growth pattern.

Lymphocytic infiltrates compound approx. 5 percent of the tissue cells.

Melanophages are present.

Diagnosis: Parts of a malignat tumor, consistent with a metastasis of a melanoma.

496 Site: lung

Dr.

Primary Tumor Site Discrepancy not stated on path		

Source: NCI Genomic Data Commons file a8434053-e14a-422d-b5a2-9ef70aef89f0 (TCGA-FS-A1ZQ.A1E704CD-0D4D-4CCC-82B2-19289EEE84EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).